Somatic mutation profile of tumor specimen TCGA-B6-A0RQ-01A (aliquot TCGA-B6-A0RQ-01A-11D-A10Y-09) from TCGA case TCGA-B6-A0RQ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.5 years (25,010 days).
Specimen TCGA-B6-A0RQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 035ca44c-491b-4e50-8aa5-2c04150a0095.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0RQ-10A (Blood Derived Normal), aliquot TCGA-B6-A0RQ-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06fa1ba1-d3a9-4e8a-9abc-06de2c870633

The open-access MAF lists 47 somatic variants for this specimen: 35 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 11, Nonsense Mutation 2, Frame Shift Del 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | hotspot (GDC flag); catalogued as COSV55726950; called by muse, mutect2, varscan2
- PIK3CA | c.1625A>G p.E542G | Missense Mutation (SNP) | VAF 16/138 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as rs1057519927, COSV55876800, COSV55881194, COSV55893680; ClinVar: likely pathogenic; called by muse, varscan2
- ANK3 | c.9292T>C p.F3098L | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.048); catalogued as COSV99780359; called by muse, mutect2
- ARAF | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs62636600, COSV99283168, COSV99283178; called by muse, mutect2
- CCDC17 | c.802T>C p.W268R | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1199064311; called by muse, mutect2
- CCNI2 | c.439T>C p.C147R | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV66394001; called by muse, mutect2
- CDH23 | c.7153G>A p.E2385K | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.837); catalogued as COSV99821452; called by muse, mutect2
- CDH8 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 7/184 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100182006; called by muse, mutect2
- CPQ | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as COSV99612624; called by muse, mutect2
- HACD1 | c.495A>C p.E165D | Missense Mutation (SNP) | VAF 10/199 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV100778498; called by muse, mutect2
- HECW2 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99647449; called by muse, mutect2
- HSF2BP | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs746694843, COSV99375558; called by muse, mutect2
- KIR3DL2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs376049512, COSV54390025; called by muse, mutect2, varscan2
- KPNB1 | c.2630G>A p.*877= | Splice Region (SNP) | VAF 12/179 reads (7%) | catalogued as COSV99268181; called by muse, mutect2
- KRT4 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs200953989; called by muse, mutect2
- MARF1 | c.3766G>A p.E1256K | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100706014; called by muse, mutect2
- MGAT4C | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100153028; called by muse, mutect2
- MYH7 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1318155896, COSV62516918; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAV2 | c.6098C>T p.S2033F (on ENST00000396087 / NM_001244963.2; = p.S1974F on NM_145117.5) | Missense Mutation (SNP) | VAF 37/491 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.543); catalogued as rs751945616, COSV60663114; called by muse, mutect2
- NUTM2F | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.137); catalogued as COSV99480175; called by muse, mutect2
- OBSCN | c.21184C>T p.P7062S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV62186058; called by muse, mutect2, varscan2
- PNLIPRP3 | c.81T>A p.C27* | Nonsense Mutation (SNP) | VAF 28/273 reads (10%) | catalogued as COSV100982505; called by muse, mutect2
- PNMA2 | c.606G>C p.K202N | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV72908475; called by muse, mutect2, varscan2
- POC1B | c.1373A>G p.D458G | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs748606086, COSV100544272; called by muse, mutect2
- PPP1R16B | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1236955516, COSV55374962; called by muse, mutect2, varscan2
- RPS6KA2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 9/226 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as COSV99691189; called by muse, mutect2
- TP53BP1 | c.5551G>A p.G1851R | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99539115; called by muse, mutect2
- TRDN | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 23/410 reads (6%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs201899630, COSV100523399; ClinVar: uncertain significance; called by muse, mutect2
- TSC2 | c.4346C>G p.S1449C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as rs759004251, COSV51912059; called by muse, mutect2, varscan2
- UBR5 | c.6419C>T p.S2140F | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV99641093; called by muse, mutect2
- USH2A | c.11044G>A p.E3682K | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV56348201, COSV56358604; called by muse, mutect2
- ZNF536 | c.3427G>A p.E1143K | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs766068117, COSV100835315; called by muse, mutect2
- DEPDC1 | c.657del p.Q219Hfs*3 | Frame Shift Del (DEL) | VAF 61/589 reads (10%) | called by mutect2, pindel, varscan2
- UBR4 | c.5636G>A p.G1879E | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2
- VSX1 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2
- ACSBG2 | c.714G>A p.K238= | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as COSV99397350, COSV99397457; called by muse, mutect2
- GHITM | c.597G>A p.V199= | Silent (SNP) | VAF 29/376 reads (8%) | catalogued as COSV100930094; called by muse, mutect2
- KCNF1 | c.999G>A p.V333= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as COSV54462248; called by muse, mutect2
- KLHL41 | c.1239G>C p.S413= | Silent (SNP) | VAF 21/196 reads (11%) | catalogued as COSV99500412; called by muse, mutect2
- KRT13 | c.658C>T p.L220= | Silent (SNP) | VAF 29/328 reads (9%) | catalogued as COSV55838929; called by muse, mutect2
- MGMT | c.549C>T p.S183= (on ENST00000306010; = p.S152= on NM_002412.5) | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs1463290575, COSV60023137; called by muse, mutect2, varscan2
- PITPNM3 | c.1080C>T p.L360= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as COSV52593482; called by mutect2, varscan2
- POLDIP3 | c.48G>A p.A16= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs752460845, COSV99349136; called by mutect2, varscan2
- TAGLN | c.564C>A p.A188= | Silent (SNP) | VAF 15/126 reads (12%) | catalogued as COSV54063015; called by muse, mutect2, varscan2
- TTN | c.68886G>A p.L22962= (on ENST00000591111; = p.L15538= on NM_003319.4) | Silent (SNP) | VAF 12/166 reads (7%) | catalogued as rs1453850244; called by muse, mutect2
- XPO4 | c.2661A>G p.Q887= | Silent (SNP) | VAF 21/235 reads (9%) | catalogued as COSV99688702; called by muse, mutect2
- ARL14EP | c.-2G>T | 5'UTR (SNP) | VAF 10/77 reads (13%) | catalogued as rs781424349, COSV99955964; called by muse, mutect2, varscan2
